Somatic mutation profile of tumor specimen MP2PRT-PAVZKX-TMP1-A (aliquot MP2PRT-PAVZKX-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PAVZKX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,226 days).
Specimen MP2PRT-PAVZKX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e19a892a-7915-4423-87b9-4b1c66ddeda7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVZKX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVZKX-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ea3b1d4-199b-4a4a-a988-5e9a63bec4b6

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Splice Site 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH3 | c.6472G>A p.E2158K | Missense Mutation (SNP) | VAF 94/354 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760584539, COSV54532648; called by muse, mutect2, varscan2
- RAD50 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769853458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN3B | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 119/417 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.285); catalogued as rs1477450173, COSV54797924; called by muse, mutect2, varscan2
- CELSR3 | c.6065+1G>T p.X2022_splice | Splice Site (SNP) | VAF 87/339 reads (26%) | called by muse, mutect2, varscan2
- CSMD3 | c.6441del p.F2147Lfs*8 (on ENST00000297405 / NM_001363185.1; = p.F2043Lfs*8 on NM_052900.3) | Frame Shift Del (DEL) | VAF 38/167 reads (23%) | called by mutect2, pindel, varscan2
- PLK2 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 97/362 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBA2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 101/296 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PXDN | c.3924C>T p.D1308= | Silent (SNP) | VAF 115/404 reads (28%) | catalogued as COSV99414610; called by muse, mutect2
- SLC2A6 | c.654G>A p.P218= | Silent (SNP) | VAF 204/606 reads (34%) | catalogued as rs782634358, COSV52471266; called by muse, mutect2, varscan2
